Gene-level copy-number profile of tumor specimen TCGA-OR-A5JX-01A from TCGA case TCGA-OR-A5JX, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 50.4 years (18,402 days).
Specimen TCGA-OR-A5JX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.4ab4aa74-991a-43e6-af3e-afb71e7bbc6c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JX-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2293d766-3c79-47f7-9f7c-b31ea352490d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,616; copy number 2: 14,659; copy number 3: 19,629; copy number 4: 18,380; copy number 5: 2,227; copy number 6: 2,139; copy number 7: 159.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JX-01A-11D-A29H-01): tumor purity 0.89, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:28,794,555–29,168,333, 11 genes (within-gene range 0–1): XBP1, Z93930.2, Z93930.3, Z93930.1, ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 159 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:107,699,392–112,867,582, 68 genes, copy number 7 (broad region; genes not listed).
- chr5:127,290,796–132,488,702, 69 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:132,419,416–132,473,043, 3 genes, copy number 7: LINC02863, Y_RNA, AC116366.1.
- chr5:168,661,733–169,301,139, 1 gene, copy number 7 (within-gene range 6–7): SLIT3.
- chr5:168,993,000–170,335,508, 18 genes, copy number 7: AC011389.1, AC011389.2, SLIT3-AS1, MIR585, RNU6-477P, SPDL1, DOCK2, AC008680.1, INSYN2B, MIR378E, FOXI1, KRT18P41, LINC01187, C5orf58, LCP2, AC034199.2, LINC01366, AC034199.1.

Autosomal genes at a single copy (total copy number 1): 2,616. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
